Somatic mutation profile of tumor specimen TARGET-10-PAPERM-09A (aliquot TARGET-10-PAPERM-09A-01D) from TARGET case TARGET-10-PAPERM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (890 days).
Specimen TARGET-10-PAPERM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a5f7544-d616-4724-abe1-86d0a12a6779.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPERM-14A (Bone Marrow Normal), aliquot TARGET-10-PAPERM-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/618c1938-cd31-47b1-bf5e-be34b592426e

The open-access MAF lists 28 somatic variants for this specimen: 22 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 3, Intron 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADRA2A | c.1339G>C p.D447H | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54526955, COSV99701732; called by muse, mutect2
- AMACR | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs761488582; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGEF10 | c.257C>A p.A86E (on ENST00000398564; = p.A62E on NM_014629.4) | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.011); catalogued as rs761339369; called by muse, mutect2
- DNAH9 | c.7361C>A p.T2454K | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52363465, COSV52377010; called by muse, mutect2
- DPYD | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as COSV60077757; called by muse, mutect2
- GHITM | c.844G>A p.G282S | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); catalogued as rs762040867, COSV100930058, COSV64538973; called by muse, mutect2, varscan2
- MYBL1 | c.896G>T p.G299V | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as rs1237479685; called by muse, mutect2
- NPY5R | c.1303G>C p.D435H | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV58451456; called by muse, mutect2, varscan2
- POTEC | c.860T>C p.V287A | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1412173441, COSV100743208, COSV62803943; called by muse, mutect2, varscan2
- PPP2R1A | c.265C>A p.L89M | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59047945; called by muse, mutect2
- TRIM77 | c.1141C>A p.L381I | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0.259); catalogued as COSV68065525; called by muse, mutect2, varscan2
- CLTCL1 | c.1399G>T p.V467F | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2
- CSTF2 | c.1285G>A p.G429R | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- IGHV1-69 | chr14:106714675 CACTGTGTCTCTCGCACAGTAATAC>GGA | Missense Mutation (DEL) | VAF 28/115 reads (24%) | called by pindel, varscan2*
- IGSF11 | c.41C>G p.S14C | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2
- KIAA1210 | c.3017T>C p.I1006T | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RUFY4 | c.799G>C p.E267Q | Missense Mutation (SNP) | VAF 7/169 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.502); called by muse, mutect2
- SLC7A3 | c.1540G>A p.V514M | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.427); called by muse, mutect2, varscan2
- SMC1B | c.2185G>T p.A729S | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.73); PolyPhen benign (0.025); called by muse, varscan2
- TTC26 | c.1009G>A p.D337N | Missense Mutation (SNP) | VAF 11/189 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2
- USH2A | c.7994G>A p.G2665E | Missense Mutation (SNP) | VAF 13/165 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.277); called by muse, mutect2
- YME1L1 | c.1021G>T p.V341F (on ENST00000326799 / NM_139312.3; = p.V284F on NM_014263.4) | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- BUB1B | c.3117G>A p.G1039= | Silent (SNP) | VAF 15/243 reads (6%) | called by muse, mutect2
- PER2 | c.1110C>A p.L370= | Silent (SNP) | VAF 15/120 reads (13%) | called by muse, mutect2, varscan2
- PLEKHG3 | c.2898C>A p.V966= (on ENST00000394691; = p.V1022= on NM_001308147.2) | Silent (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2
- TGFBR2 | c.*6C>T | 3'UTR (SNP) | VAF 11/168 reads (7%) | catalogued as COSV55448063; called by muse, mutect2
- TMEM191C | c.472-51C>T | Intron (SNP) | VAF 9/49 reads (18%) | catalogued as rs3819059; called by muse, mutect2
- TWF1 | c.25+172G>T | Intron (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
